Surgical pathology report (de-identified scan), TCGA case TCGA-35-3615, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Cureline, specimen TCGA-35-3615-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED]

Index						Ethnicity (Race)	Clinical Diagnosis
1						[REDACTED]	Lung cancer
						[REDACTED]	Lung cancer

[page 2 of 4]
[REDACTED]

[REDACTED]

Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount/per container
[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]
[REDACTED]	Lung	Primary	Tumor	Tissue	OCT	block	1	n/a
[REDACTED]	Blood	n/a	Normal	Blood	frozen	tube	1	n/a

[page 3 of 4]
Unit	Type of Procurement	Histological description (Source)	Grade (source)	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type
n/a	surgery	Adenocarcinoma	2	2	0	0	none
n/a	blood draw	n/a	n/a	n/a	n/a	n/a	none

[page 4 of 4]
Component of treatment (Chemo / Horm Th Details)	Tumor cell %
n/a	over 50
n/a	n/a

Source: NCI Genomic Data Commons file 333d3e99-68d2-44f7-b00a-4e88a34fb63a (TCGA-35-3615.FFC829B9-9E11-41C9-9532-B6303AD48A9F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).